Somatic mutation profile of tumor specimen TARGET-10-PARASZ-09A (aliquot TARGET-10-PARASZ-09A-01D) from TARGET case TARGET-10-PARASZ, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.4 years (1,610 days).
Specimen TARGET-10-PARASZ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 58bbf299-3218-4204-a6f9-7ebb2c95ce65.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARASZ-10A (Blood Derived Normal), aliquot TARGET-10-PARASZ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5a0f0bb6-9dfb-443e-be74-1a9cafed9c43

The open-access MAF lists 20 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Intron 4, Silent 3, Nonsense Mutation 2, Frame Shift Ins 1, In Frame Del 1, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRL2 | c.2635C>T p.R879* (on ENST00000370717 / NM_001366005.1; = p.R866* on NM_012302.4) | Nonsense Mutation (SNP) | VAF 32/91 reads (35%) | catalogued as COSV54672534; called by muse, mutect2, varscan2
- CACNA1D | c.5644C>T p.R1882* (on ENST00000350061 / NM_001128840.3; = p.R1902* on NM_000720.4) | Nonsense Mutation (SNP) | VAF 31/94 reads (33%) | catalogued as COSV55451637; called by muse, mutect2, varscan2
- EPHB4 | c.1483C>T p.R495W | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as rs761482515, COSV62269327; called by muse, mutect2, varscan2
- GOLGA6L2 | c.1760C>T p.A587V | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated, low confidence (0.69); catalogued as rs1222637028; called by muse, mutect2, varscan2
- GRIK5 | c.690C>T p.A230= | Splice Region (SNP) | VAF 18/50 reads (36%) | catalogued as rs986767655; called by muse, mutect2, varscan2
- NOTCH1 | c.7391_7395dup p.T2466Cfs*13 | Frame Shift Ins (INS) | VAF 5/29 reads (17%) | catalogued as COSV53072211; called by mutect2, varscan2
- NOTCH1 | c.5033T>C p.L1678P | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV53024869, COSV53029241; called by muse, mutect2, varscan2
- OSBPL10 | c.908C>T p.A303V | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as rs749055456, COSV101159864, COSV67340456; called by muse, varscan2
- PCDH11X | c.2622G>T p.K874N | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.977); catalogued as COSV53475312, COSV53511029, COSV53513988; called by muse, mutect2
- PCLO | c.12752A>G p.D4251G | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV61641877; called by muse, mutect2, varscan2
- PPARGC1A | c.2389C>T p.R797C | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs34129331; called by muse, mutect2, varscan2
- NOTCH1 | c.4852_4857del p.P1618_Y1619del | In Frame Del (DEL) | VAF 9/49 reads (18%) | called by mutect2, pindel, varscan2
- C17orf99 | c.240G>A p.P80= | Silent (SNP) | VAF 44/105 reads (42%) | catalogued as rs369271923; called by muse, mutect2, varscan2
- HAND2 | c.369C>T p.R123= | Silent (SNP) | VAF 20/84 reads (24%) | called by muse, mutect2, varscan2
- VWA3A | c.2331G>A p.P777= | Silent (SNP) | VAF 23/59 reads (39%) | catalogued as rs771251570; called by muse, mutect2, varscan2
- AC092656.1 | n.303-21C>A | Intron (SNP) | VAF 22/72 reads (31%) | called by muse, varscan2
- AP2A2 | c.*447C>T | 3'UTR (SNP) | VAF 24/67 reads (36%) | catalogued as rs771901429, COSV100172927; called by muse, mutect2, varscan2
- CFAP58 | c.1365+2024T>C | Intron (SNP) | VAF 20/43 reads (47%) | catalogued as rs989877508; called by muse, mutect2, varscan2
- TCEA2 | c.517+61C>T | Intron (SNP) | VAF 11/38 reads (29%) | called by muse, mutect2, varscan2
- TTN | c.10360+2255C>G | Intron (SNP) | VAF 20/107 reads (19%) | catalogued as COSV60131379; called by muse, mutect2, varscan2
